CCDI case PBBIKD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f6854ff5-9284-4cc1-8e16-22b5a152b39c

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,365 days).

Biospecimens (3 samples)
- Sample 0DA6QG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DA6QR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DA6R2: Tissue type: Tumor; Specimen type: Solid Tissue.
